Gene-level copy-number profile of tumor specimen TCGA-AO-A12C-01A from TCGA case TCGA-AO-A12C, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 42.4 years (15,469 days).
Specimen TCGA-AO-A12C-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.2e146555-16fd-4c9a-b907-6c440fcd58fd.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AO-A12C-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate.
https://portal.gdc.cancer.gov/files/53690b68-7b76-4d62-9863-38f8d83ce19d

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 7,971; copy number 3: 1,711; copy number 4: 42,721; copy number 5: 1,639; copy number 6: 4,274; copy number 8: 432; copy number 9: 84; copy number 10: 540; copy number 11: 437; copy number 13: 11.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,072 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr17:142,789–1,900,082, 61 genes, copy number 10 (broad region; genes not listed).
- chr17:16,929,816–22,288,301, 272 genes, copy number 10 (within-gene range 2–10) (broad region; genes not listed).
- chr17:47,409,322–54,365,634, 218 genes, copy number 10–13 (within-gene range 8–13) (broad region; genes not listed).
- chr17:67,070,444–70,779,230, 84 genes, copy number 9 (within-gene range 6–9) (broad region; genes not listed).
- chr19:53,333,749–58,605,223, 437 genes, copy number 11 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
